Gene-level copy-number profile of tumor specimen TCGA-3A-A9IV-01A from TCGA case TCGA-3A-A9IV, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 59.5 years (21,732 days).
Specimen TCGA-3A-A9IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.b462ab8a-8a17-4384-8e25-b0ce1f869851.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9IV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d80fe56f-2722-4424-9f4e-68ac0d68fb8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 133; copy number 2: 33,656; copy number 3: 6,006; copy number 4: 19,265; copy number 5: 627; copy number 6: 123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9IV-01A-11D-A40V-01): tumor purity 0.85, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 750 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:96,941,281–97,730,339, 15 genes, copy number 6: TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2.
- chr14:21,887,857–22,525,715, 99 genes, copy number 6 (broad region; genes not listed).
- chr18:45,104,361–45,683,688, 9 genes, copy number 6 (within-gene range 4–6): AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1.
- chr19:94,062–11,619,161, 627 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 133. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
